Gene-level copy-number profile of tumor specimen MP2PRT-PASJVH-TBP1-A from MP2PRT case MP2PRT-PASJVH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,799 days).
Specimen MP2PRT-PASJVH-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed0de023-3f6e-496b-997d-aef46b585c1a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASJVH-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/e0528dce-546e-4991-8924-94d989975fe5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 160; copy number 2: 44,394; copy number 3: 13,073; copy number 4: 35; copy number 6: 6; copy number 7: 722.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 728 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:9,975,017–10,119,309, 1 gene, copy number 6 (within-gene range 3–6): CR382285.1.
- chr21:10,122,273–10,358,620, 5 genes, copy number 6: CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P.
- chr21:13,038,160–46,691,226, 722 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
